Surgical pathology report (de-identified scan), TCGA case TCGA-06-0414, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0414-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

MRN:

Birth Date:

Sex: M

Room/Bed:

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX:

SURGERY DATE:

PHYSICIAN:

RECEIVE DATE:

COPY TO:

UPDATED REPORT - SEE SPECIAL STAIN REPORT, ADDENDUM

COMMENT.

UPDATED REPORT - SEE ADDENDUM REPORT

PATHOLOGICAL DIAGNOSIS:A AND B. BRAIN, RIGHT OCCIPITAL, BIOPSY: MALIGNANT GLIOMA,
RECURRENT.SPECIAL STAIN REPORT: MIB-1 STAIN: 80%.

Operation/Specimen: Brain, right occipital.

Clinical History and Pre-Op Dx: year old man with diagnosis of
glioblastoma multiforme two years ago. Now has recurrence.GROSS PATHOLOGY: A. Received fresh, two fragments, 0.6 cm across in
aggregate. Tannish-gray, soft. In total #1.INTRAOPERATIVE CONSULTATION: Brain, right occipital: Malignant
oma.

B.

SPECIMEN: R. lesion.

FIXATIVE: None.

GENERAL: Irregular portion of yellow-tan to pink gray soft tissue
2.3 x 1.5 x 0.3 cm.

SECTIONS: FS1 - all.

MICROSCOPIC: A. Minute portions of a glial neoplastic proliferation.
The neoplasm is very cellular and the neoplastic cells have features of
anaplasia, and infiltrate the surrounding brain. There is necrosis
with hyalinization. There is also neovascularization, and a few small
vessels have thick hyalinized walls.

ADDENDUM REPORT

MICROSCOPIC: B. Large portions of neoplasm, similar to that one
described for part A. In here, there is prominent neovascularization.
In addition, a small zone of the tumor has a plexiform vascular network
and some roundness to the nuclei, which occasionally have halos. This
feature suggests an oligodendroglial component.

ADDENDUM REPORT

Requested by:

[page 2 of 3]
Patient Name: |

MRN: |

Birth Date: |

Sex: M |

Room/Bed: |

ADDENDUM COMMENT: MIB-1 of the tumor cells is about 80%.

TISSUE COMMITTEE CODE:
BILLING CODES:

Requested by:

[page 3 of 3]
Patient Name:

MRN:

Birth Date:

Sex: Male Room/Bed:

PATIENT NAME:

HIST. NO.:

AGE/SEX:

M

ACC. NO.:

ORDERING PHYSICIAN:

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX:

M

DOB:

SURGERY DATE:

RECEIVE DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:

RIGHT TEMPORAL BIOPSY: GLIOBLASTOMA MULTIFORME, (PROLIFERATIVE INDEX ABOUT 30%).

Operation/Specimen: 1 R temporal tumor.

Clinical History and Pre-Op Dx: #2

GROSS PATHOLOGY: A. Multiple small red-white soft tissue. Portion has been examined by frozen section and submitted in cassette 1. Rest in cassette 2.

B. Two portions of brain parenchyma. 4 x 3 x 1 cm and 3 x 3 x 1 cm. Representative sections in #4-7.

MICROSCOPIC: Sections show an infiltrating glioblastoma with high cellular density, nuclear pleomorphism, prominent vascular-endothelial hyperplasia and patchy areas of tumor necrosis. The proliferative index as measured by immunostain for MIB-1 (Ki-67) is about 30%.

TISSUE COMMITTEE CODE:

BILLING CODES

Source: NCI Genomic Data Commons file 4417bc75-ae6d-419f-a4c9-78bacac5c88e (TCGA-06-0414.636B42B6-1B1A-42C2-B8E4-73294B5E004B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).